CCDI case PBBSHJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9ad61234-5df6-4174-81a5-bfd5ff1706f5

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Choroid plexus carcinoma: ICD-O-3 morphology code: 9390/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 2.2 years (809 days).

Biospecimens (3 samples)
- Sample 0DG84E: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DG858: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DG87O: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
